MMRF case MMRF_2412 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6372dd4a-2f71-4780-8144-83a574964db1

Demographics
Sex at birth: female; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.9 years (24,058 days); ISS stage: III; Days to last known disease status: 718 days (2.0 years); Days to last follow up: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 164 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 718.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 840 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 31.9 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 248 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.01 mmol/L.
- Day 63 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 82.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 3.2 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 4.96 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 5.3 g/dL; Glucose 5.06 mmol/L.
- Day 164 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 121 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 2.79 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 4.84 mmol/L.
- Day 212 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 83.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 3.35 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 3.91 mmol/L.
- Day 354 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 125 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 458 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 102 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 6.11 mmol/L.
- Day 521 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 4.21 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 6.05 mmol/L.
- Day 644 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 152 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 3.81 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 694: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 143 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 3.72 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day 0: Weight: 50 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2412_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2412_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
